Somatic mutation profile of tumor specimen MP2PRT-PAUSVG-TMP1-A (aliquot MP2PRT-PAUSVG-TMP1-A-1-0-D-A819-36) from MP2PRT case MP2PRT-PAUSVG, project MP2PRT-ALL (Molecular Profiling to Predict Response to Treatment for Acute Lymphoblastic Leukemia). Sex at birth: female; Vital status: Alive; Primary diagnosis: Common precursor B ALL; Tissue or organ of origin: Bone marrow; Age at diagnosis: 4.9 years (1,797 days).
Specimen MP2PRT-PAUSVG-TMP1-A: Sample type: Blood Derived Cancer - Bone Marrow; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Whole Bone Marrow; Biospecimen anatomic site: Bone Marrow; Preservation method: Cryopreserved.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 59c07e8d-e16a-453a-b3c4-692ba1ec88f3.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen MP2PRT-PAUSVG-NB1-A (Blood Derived Cancer - Peripheral Blood, Post-treatment; tissue type Normal — post-treatment blood used as the germline comparator), aliquot MP2PRT-PAUSVG-NB1-A-1-0-D-A819-36; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/f4c7e44f-8254-43db-a8fe-defb6b1dfd1a

The open-access MAF lists 14 somatic variants for this specimen: 8 protein-altering or splice-affecting, 5 silent, 1 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 6, Silent 5, 3'Flank 1, Frame Shift Del 1, Nonsense Mutation 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- NRAS | c.179G>A p.G60E | Missense Mutation (SNP) | VAF 132/337 reads (39%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as rs267606920, CM100127, COSV54736394, COSV54741067; ClinVar: pathogenic; called by muse, mutect2, varscan2
- CSMD3 | c.7745G>A p.S2582N (on ENST00000297405 / NM_001363185.1; = p.S2478N on NM_052900.3) | Missense Mutation (SNP) | VAF 128/334 reads (38%) | SIFT tolerated (0.52); PolyPhen probably damaging (0.984); catalogued as rs1170645791; called by muse, mutect2, varscan2
- EDA2R | c.40C>T p.R14W | Missense Mutation (SNP) | VAF 147/561 reads (26%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.469); catalogued as rs144036451, COSV53630319; called by muse, mutect2, varscan2
- EZHIP | c.1220G>A p.R407H | Missense Mutation (SNP) | VAF 264/803 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.975); catalogued as rs1226291397, COSV100539828; called by muse, mutect2, varscan2
- WLS | c.473G>A p.R158Q | Missense Mutation (SNP) | VAF 109/260 reads (42%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs370140589; called by muse, mutect2, varscan2
- AKAP14 | c.166G>T p.E56* | Nonsense Mutation (SNP) | VAF 97/325 reads (30%) | called by muse, mutect2, varscan2
- MRPL39 | c.380_389del p.F127Sfs*9 | Frame Shift Del (DEL) | VAF 183/351 reads (52%) | called by mutect2, pindel, varscan2
- TRPC5 | c.1670G>A p.R557Q | Missense Mutation (SNP) | VAF 168/558 reads (30%) | SIFT tolerated (0.08); PolyPhen probably damaging (0.979); called by muse, mutect2, varscan2
- ARFGAP3 | c.1374G>C p.S458= | Silent (SNP) | VAF 155/339 reads (46%) | called by muse, mutect2, varscan2
- CCDC175 | c.2067C>T p.S689= | Silent (SNP) | VAF 99/335 reads (30%) | catalogued as rs4394993; called by muse, mutect2, varscan2
- NAA11 | c.309C>T p.N103= | Silent (SNP) | VAF 140/536 reads (26%) | catalogued as rs764751693; called by muse, mutect2, varscan2
- PDILT | c.1653C>T p.P551= | Silent (SNP) | VAF 162/381 reads (43%) | catalogued as rs369605247; called by muse, mutect2, varscan2
- SLC5A2 | c.345C>T p.P115= | Silent (SNP) | VAF 189/480 reads (39%) | catalogued as rs779593918, COSV57890633; called by muse, mutect2, varscan2
- IGHV4-61 | chr14:106639118 ins CCTCTTCCGA | 3'Flank (INS) | VAF 22/62 reads (35%) | called by pindel, varscan2
